Somatic mutation profile of tumor specimen TCGA-ZC-AAAA-01A (aliquot TCGA-ZC-AAAA-01A-11D-A428-09) from TCGA case TCGA-ZC-AAAA, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 39.5 years (14,429 days).
Specimen TCGA-ZC-AAAA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45b82a8a-f19f-4b7d-8f1b-cf60583f791a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZC-AAAA-10A (Blood Derived Normal), aliquot TCGA-ZC-AAAA-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3d41f1f-c5f6-4316-beea-65c71c5db489

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQCA1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771403726, COSV54494846; called by mutect2, varscan2
- CLIP2 | c.2920C>A p.L974I | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2
- DOCK6 | c.778A>G p.R260G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- H2AC6 | c.12T>C p.R4= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1407296791; called by muse, mutect2
